Surgical pathology report (de-identified scan), TCGA case TCGA-BB-A5HU, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Johns Hopkins, specimen TCGA-BB-A5HU-01A (Primary Tumor).

[page 1 of 2]
SURG PATH REPORT

Carcinoma, Squamous Cell
8070/13
Site: Oral Cavity C06.9
Jan 11/28/13

FINAL DIAGNOSIS ----- Pathologist:

1. ANTERIOR MANDIBULAR MARGIN (EXCISION): NEGATIVE FOR TUMOR.
2. POSTERIOR MANDIBULAR MARGIN (EXCISION): NEGATIVE FOR TUMOR.
3. MEDIAL MUCOSAL MARGIN (EXCISION): NEGATIVE FOR TUMOR.
4. ANTERIOR MUCOSAL MARGIN (EXCISION): NEGATIVE FOR TUMOR.
5. POSTERIOR BUCCAL MUCOSA MARGIN (EXCISION): NEGATIVE FOR TUMOR.
6. ANTERIOR BUCCAL MUCOSA MARGIN (EXCISION): NEGATIVE FOR TUMOR.
7. POSTERIOR MUCOSA MARGIN (EXCISION): NEGATIVE FOR TUMOR.
8. SKIN, FOREHEAD (EXCISION): BASAL CELL CARCINOMA (NODULAR VARIANT, 0.8CM), MARGINS ARE UNINVOLVED.

9. COMPOSITE ORAL CAVITY:

SPECIMEN TYPE:

Resection (specify type): Partial mandibulectomy.

TUMOR SITE:

Oral cavity (right mandible).

TUMOR SIZE:

Greatest dimension: 4.5cm.

HISTOLOGIC TYPE:

Carcinomas of upper aerodigestive tract: squamous cell carcinoma, conventional.

HISTOLOGIC GRADE:

G2: Moderately differentiated.

EXTENT OF INVASION (7th Edition AJCC):

PRIMARY TUMOR (pT):

pT4: Tumor invades through cortical bone.

REGIONAL LYMPH NODES (pN):

pN2b: Metastasis in multiple ipsilateral lymph nodes.

Specify: Number examined: 37

Number involved: 6

Extracapsular extension of nodal tumor:

Present.

MARGINS:

Margins uninvolved by tumor.

VENOUS/LYMPHATIC (LARGE/SMALL VESSEL) INVASION:

Indeterminate.

PERINEURAL INVASION:

Present.

ADDITIONAL PATHOLOGIC FINDINGS:

LEVEL 1: METASTATIC SQUAMOUS CELL CARCINOMA INVOLVING 5 OF 7 LYMPH NODES.

10. RIGHT NECK LEVELS 2, 3, 4 (NECK DISSECTION):

*** Unofficial lab results - do not file in patient chart. ***

*** Contact medical records for official chart copy. ***

UNLESS OTHERWISE NOTED ON THE DETAIL PAGE, ALL LAB RESULTS PERFORMED AT:

[page 2 of 2]
LEVEL 2: METASTATIC SQUAMOUS CELL CARCINOMA INVOLVING 1 OF 13 LYMPH
NODES. TUMOR DEPOSIT MEASURES 1.5CM.

LEVEL 3: 6 LYMPH NODES AND ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE
FOR TUMOR.

LEVEL 4: 11 LYMPH NODES AND ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE
FOR TUMOR.

has reviewed key parts of this case.

*** Unofficial lab results - do not file in patient chart. ***

*** Contact medical records for official chart copy. ***

UNLESS OTHERWISE NOTED ON THE DETAIL PAGE, ALL LAB RESULTS PERFORMED AT:

Criteria	1/24/13	Yes	No
Pathology Discrepancy			✓
Other Discrepancy History			
Asynchronous Primary			
Other			

Source: NCI Genomic Data Commons file 818e4ee3-9e46-4475-b3ee-fcb6d68ff64f (TCGA-BB-A5HU.317C24E3-3F0F-4685-AC67-FF1F6B7C9087.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).